Surgical pathology report (de-identified scan), TCGA case TCGA-BS-A0UF, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii, specimen TCGA-BS-A0UF-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

adenocarcinoma, endometrioid, Nos 8380/3
Site: Endometrium c54.1 lw 51.11

Surgical Pathology Report

Patient Name:

Med. Rec. #:

DOB:

Gender:

Physician(s):

cc:

Client:

Location:

Accession #:

Taken:

Received:

Reported:

History/Clinical Dx: Endometrial cancer

Postoperative Dx: Pending pathology examination

Specimen(s) Received:

- A: Left pelvic lymph node
- B: Left aortic lymph node
- C: Right pelvic lymph node
- D: Right aortic lymph node
- E: Uterus, cervix, tubes and ovaries

DIAGNOSIS:

- A. Left pelvic lymph nodes: Four lymph nodes negative for metastasis (0/4)
- B. Left aortic lymph nodes: Two lymph nodes negative for metastasis (0/2)
- C. Right pelvic lymph nodes: Five lymph nodes negative for metastasis (0/5)
- D. Right aortic lymph nodes: Two lymph nodes negative for metastasis (0/2)
- E. Uterus, cervix, tubes and ovaries: ENDOMETRIAL ADENOCARCINOMA

Tumor Information:

Operative procedure:	TAH-BSO with node sampling
Histologic type:	Endometrioid
Histologic grade(FIGO):	Grade 3
Nuclear grade:	3
Tumor size:	1.4 x 0.7 x 0.6 cm
Extent of invasion:	Less than 50% (3 mm invasion/10 mm myometrial thickness)
Lympho/vascular invasion:	Not identified
Serosa:	Free of tumor
Parametrium:	Free of tumor
Cervical involvement:	Absent
Right adnexa:	Free of tumor
Left adnexa:	Free of tumor
Pelvic washings:	Negative
Other findings:	Adenomyosis
Staging information:	T1b, N0

Regulatory Statement

This following statement may be applicable to some of the reagents/antibodies used in developing the above report: This test was developed and its performance characteristics determined by the manufacturer. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that each reagent or antibody is not necessary. This test is used for clinical purposes. It should not be regarded as a replacement of the manufacturer's instructions. The laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

[page 2 of 3]
Surgical Pathology Report

Gross Description

- A. Received in formalin labeled "left pelvic lymph node" are two pieces of fibroadipose tissue, aggregating up to 3.5 x 3.3 x 1.5 cm. There are four possible lymph nodes grossly identified, the largest up to 1.7 x 1.2 x 0.3 cm. Submitted in toto in four cassettes.
- B. Received in formalin labeled "left aortic lymph node" are two pieces of fibroadipose tissue, aggregating up to 2.0 x 0.4 cm. There are two possible lymph nodes grossly identified with the largest up to 1.2 x 0.6 x 0.4 cm. Submitted in toto in one cassette.
- C. Received in formalin labeled "right pelvic lymph node" is a single piece of fibroadipose tissue, 3.0 x 3.0 x 1.4 cm. There are five lymph nodes grossly identified, the largest up to 0.6 x 0.5 x 0.4 cm. Submitted in toto in three cassettes.
- D. Received in formalin labeled "right aortic lymph node" is a single piece of fibroadipose tissue, 1.9 x 1.5 x 0.7 cm. There are two lymph nodes grossly identified, largest up to 0.9 x 0.5 x 0.4 cm. Submitted in toto in one cassette.
- E. Received: In formalin is previously opened, unoriented single piece of soft tan to white tissue, with a separately received segment of soft tan to white tissue with surrounding clotted blood
- Labeled: Uterus, cervix, tubes and ovaries
- Weight: 45 gms
- Size:
- Uterus: 6.8 x 2.9 x 2.7 cm
- Right ovary (inked blue): 1.3 x 0.6 x 0.5 cm
- Left ovary: Not grossly identified
- Appearance
- Tumor
- Location: Left fundus
- Size: 1.4 x 0.7 x 0.6 cm
- Appearance: Polypoid, tan, soft
- Depth of invasion: Grossly appears superficial, with no gross involvement of the myometrium
- Invasion of contiguous structures: None grossly identified
- Distance from margins: 4.9 cm from the cervical margin
- Cervix: Grossly unremarkable
- Endometrium: Less than 0.1 cm, soft, tan
- Myometrium: 1.3 cm in thickness. No gross evidence of adenomyosis
- Right tube and ovary (inked blue): Right tube measures 5.4 x 0.5 x 0.4 cm, and is grossly unremarkable. There is indications of a previous tubal ligation. The right ovary is grossly unremarkable with a white homogenous cut surface.
- Left tube and ovary (inked orange): The left tube and ovary are not grossly identified
- Lymph nodes: None
- Special studies: None
- Other: Separately received soft tan tissue and clotted blood, aggregating up to 4.0 x 2.0 x 1.1 cm

KEY TO CASSETTES:

- E1 - Cervix
- E2 - Lower uterine segment, full thickness
- E3 - Tumor with underlying myometrium, full thickness
- E4 - Representative of separately received soft tan tissue and clotted blood described in other
- E5-E7 - Endomyometrium
- E8 - Right (inked blue) adnexa and area surrounding left adnexa (inked orange)
- E9 - Right (inked blue) and left (inked orange) parametrium

Microscopic Description

The microscopic findings support the above diagnosis.

[page 3 of 3]
[REDACTED] Surgical Pathology Report [REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file aec30969-4670-44dc-9e83-29d8c8dbdacc (TCGA-BS-A0UF.719E2A48-0E04-4EAD-A5CC-6416450FC68F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).